Surgical pathology report (de-identified scan), TCGA case TCGA-YT-A95D, project TCGA-THYM (Thymoma), tissue source site Barretos Cancer Hospital, specimen TCGA-YT-A95D-01A (Primary Tumor).

Collect date:
(MM/DD/YYYY)

PATHOLOGY REPORT:

PRIMARY SITE: Anterior mediastinum

1. "Anterior mediastinum"
- Type AB Thymoma (WHO 2004).
- Neoplasia size: 10.8 x 8.0 x 5.2cm.
- Surgical margin: uninvolved, although exiguous.

Note: See immunohistochemistry exam.

Immunohistochemistry exam

Morphologic aspects associated with immunohistochemistry profile are compatible with Thymoma.

ICD O 3
Thymoma type AB NOS
8582/1
Site: Anterior mediastinum
038.1
WS 11/13/14

Source: NCI Genomic Data Commons file 2de2873c-e2b6-491d-ae6e-d15b41012928 (TCGA-YT-A95D.AAEC6A80-48B3-4420-862C-9596A33922B9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).